Somatic mutation profile of tumor specimen TCGA-61-1907-01A (aliquot TCGA-61-1907-01A-01W-0639-09) from TCGA case TCGA-61-1907, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.5 years (23,204 days).
Specimen TCGA-61-1907-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bc7551c-0986-40a2-86da-819b346f6bc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1907-11A (Solid Tissue Normal), aliquot TCGA-61-1907-11A-01W-0640-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17e4f731-61a6-4605-9f7e-7438831f6943

The open-access MAF lists 124 somatic variants for this specimen: 97 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 25, Splice Site 4, Frame Shift Del 4, Nonsense Mutation 4, Splice Region 2, 3'UTR 1, 5'Flank 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL1 | c.1997C>A p.P666H | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101221814; called by mutect2, varscan2
- AGK | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.16); catalogued as CM124422, COSV100814567, COSV62595739; called by muse, mutect2, varscan2
- ANKRD12 | c.1363C>G p.Q455E | Missense Mutation (SNP) | VAF 79/604 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV50828752, COSV50842356; called by muse, mutect2, varscan2
- APPL2 | c.1982A>T p.E661V | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51593159; called by muse, mutect2, varscan2
- BAIAP2L2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV60202656; called by muse, varscan2
- BICC1 | c.2587G>C p.G863R | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.973); catalogued as COSV99570018; called by muse, mutect2
- BSND | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV64871314; called by muse, mutect2, varscan2
- CERKL | c.1031T>G p.F344C (on ENST00000339098 / NM_001030311.2; = p.F318C on NM_201548.5) | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV59206446, COSV59212734; called by muse, mutect2, varscan2
- CFAP46 | c.6013A>C p.T2005P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV54158322; called by muse, mutect2, varscan2
- CNGB1 | c.1959C>T p.N653= | Splice Region (SNP) | VAF 36/91 reads (40%) | catalogued as COSV51905808; called by muse, mutect2, varscan2
- CNPY3 | c.243C>G p.D81E | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs751837391, COSV65710024; called by muse, mutect2, varscan2
- CNTRL | c.845dup p.M283Dfs*5 | Frame Shift Ins (INS) | VAF 36/246 reads (15%) | catalogued as rs750317819; called by mutect2, varscan2
- CSMD3 | c.958A>C p.K320Q | Missense Mutation (SNP) | VAF 156/445 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52291596; called by muse, mutect2, varscan2
- CTAGE1 | c.2016G>T p.L672F | Missense Mutation (SNP) | VAF 608/891 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV66944468; called by muse, mutect2, varscan2
- CTNNBL1 | c.1437G>C p.E479D | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63746890; called by muse, mutect2, varscan2
- CYP11B1 | c.1162T>A p.S388T | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV52829848; called by muse, mutect2, varscan2
- CYP4A11 | c.1040G>A p.C347Y | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60225222; called by muse, mutect2, varscan2
- DARS1 | c.1196G>T p.R399I | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51541400; called by muse, mutect2, varscan2
- ELOVL6 | c.655T>C p.W219R | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV56431645; called by muse, mutect2, varscan2
- EXPH5 | c.431T>A p.L144Q | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.331); catalogued as COSV56207290; called by muse, mutect2, varscan2
- FAM120C | c.3176C>G p.S1059C | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV60261980; called by muse, mutect2, varscan2
- FAM160B2 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.021); catalogued as rs775211664, COSV57160688; called by muse, mutect2, varscan2
- FFAR4 | c.787T>G p.Y263D | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV65160684; called by muse, mutect2, varscan2
- FMO2 | c.627+1G>T p.X209_splice | Splice Site (SNP) | VAF 47/182 reads (26%) | catalogued as COSV99268796; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1895A>T p.H632L | Missense Mutation (SNP) | VAF 104/168 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58563892; called by muse, mutect2, varscan2
- FRRS1 | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as COSV54923965; called by muse, mutect2, varscan2
- GNB4 | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV51711438; called by muse, mutect2, varscan2
- HUWE1 | c.12317A>T p.Y4106F | Missense Mutation (SNP) | VAF 127/154 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53361334; called by muse, mutect2, varscan2
- IL6ST | c.1000T>C p.Y334H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.861); catalogued as rs753100575, COSV61142664; called by muse, mutect2, varscan2
- ITGA6 | c.3317A>G p.K1106R (on ENST00000442250; = p.K1067R on NM_001079818.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV51251896; called by muse, mutect2, varscan2
- ITGAM | c.1369T>C p.F457L | Missense Mutation (SNP) | VAF 91/226 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54941508; called by muse, mutect2, varscan2
- KCNK10 | c.996G>C p.E332D | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56651109; called by muse, mutect2, varscan2
- KERA | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57131575; called by muse, mutect2, varscan2
- KLK2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV57569317; called by muse, varscan2
- LAMA3 | c.2248C>G p.P750A | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV58077727; called by muse, mutect2, varscan2
- LEMD3 | c.2180A>T p.E727V | Missense Mutation (SNP) | VAF 9/289 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100384105; called by muse, mutect2
- LRP1 | c.8399G>T p.C2800F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54523276; called by muse, mutect2, varscan2
- LRRTM4 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69141662; called by muse, mutect2, varscan2
- LTBP2 | c.3316G>A p.G1106R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs201430837, COSV56209216; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP4 | c.1810G>T p.D604Y | Missense Mutation (SNP) | VAF 56/367 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV64243936; called by muse, mutect2, varscan2
- MS4A12 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs767822239, COSV99188401; called by muse, mutect2
- MTOR | c.4381G>T p.V1461L | Missense Mutation (SNP) | VAF 136/159 reads (86%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV63877196; called by muse, mutect2, varscan2
- NCAN | c.1745C>G p.A582G | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV53057113; called by muse, mutect2, varscan2
- NDC1 | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as rs1462384353, COSV52338304; called by muse, mutect2, varscan2
- NEDD1 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57146287; called by muse, mutect2, varscan2
- NMT2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs540952796, COSV65382035; called by muse, mutect2, varscan2
- OLFM3 | c.514C>G p.Q172E (on ENST00000338858 / NM_001288821.1; = p.Q152E on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV58802700; called by muse, mutect2, varscan2
- OPCML | c.287C>A p.T96N | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as COSV59445081; called by muse, mutect2, varscan2
- OR13G1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 89/148 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62943780; called by muse, mutect2, varscan2
- PABPC4 | c.1430C>G p.A477G | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV63293630; called by muse, mutect2, varscan2
- PAPSS2 | c.939C>A p.C313* | Nonsense Mutation (SNP) | VAF 5/72 reads (7%) | catalogued as COSV100753341; called by muse, mutect2
- PDE11A | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 145/274 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as COSV53705948; called by muse, mutect2, varscan2
- PHACTR4 | c.345A>T p.R115S (on ENST00000373839 / NM_001350159.2; = p.R125S on NM_023923.4) | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1188681224, COSV100868372; called by muse, mutect2
- PHACTR4 | c.347C>T p.S116L (on ENST00000373839 / NM_001350159.2; = p.S126L on NM_023923.4) | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV100868373; called by muse, mutect2
- PKHD1 | c.3214A>C p.K1072Q | Missense Mutation (SNP) | VAF 128/380 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs780201606, COSV61891389; called by muse, mutect2, varscan2
- PLCH1 | c.1771C>T p.R591* (on ENST00000340059 / NM_001130960.2; = p.R603* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 105/162 reads (65%) | catalogued as COSV58208391; called by muse, mutect2, varscan2
- PTPRR | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs771463912, COSV51744946; called by muse, mutect2, varscan2
- RMND1 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 5/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100323457; called by muse, mutect2
- RRBP1 | c.1832A>T p.D611V (on ENST00000377813 / NM_001365613.2; = p.D181V on NM_004587.3) | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV99853349; called by muse, mutect2
- RRP1B | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 62/89 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.207); catalogued as rs369172517; called by muse, mutect2, varscan2
- SASH1 | c.2636C>T p.A879V | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66564893; called by muse, mutect2, varscan2
- SCN11A | c.3438C>G p.F1146L | Missense Mutation (SNP) | VAF 132/375 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100182921, COSV56576683; called by muse, mutect2, varscan2
- SERPINB5 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV66975192; called by muse, mutect2, varscan2
- SETD1A | c.639G>C p.T213= | Splice Region (SNP) | VAF 34/92 reads (37%) | catalogued as COSV52691686; called by muse, mutect2, varscan2
- SLC25A20 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs371250509, COSV59803484; called by muse, mutect2, varscan2
- SLC4A8 | c.1956G>A p.W652* | Nonsense Mutation (SNP) | VAF 94/164 reads (57%) | catalogued as COSV60657344; called by muse, mutect2, varscan2
- SMC1A | c.746T>C p.I249T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as COSV59131484; called by muse, mutect2, varscan2
- SNUPN | c.934C>G p.H312D | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.368); catalogued as COSV57949369; called by muse, mutect2, varscan2
- SOCS5 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.147); catalogued as rs758847494, COSV60606160; called by muse, mutect2, varscan2
- SPEN | c.8062G>A p.G2688R | Missense Mutation (SNP) | VAF 141/164 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV65366647; called by muse, mutect2, varscan2
- SRPK2 | c.800A>C p.N267T | Missense Mutation (SNP) | VAF 116/288 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV61963665; called by muse, mutect2, varscan2
- STRAP | c.330+2del p.X110_splice | Splice Site (DEL) | VAF 24/151 reads (16%) | catalogued as COSV50308372, COSV50309165; called by mutect2, pindel, varscan2
- STT3B | c.2344G>C p.D782H | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV55505377; called by muse, mutect2, varscan2
- TENM1 | c.6611G>C p.R2204T | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV64440803; called by muse, mutect2, varscan2
- THAP12 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 77/412 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV52612723; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1303C>G p.R435G | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as COSV64955156, COSV64956369; called by muse, mutect2, varscan2
- TRIML1 | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 36/51 reads (71%) | catalogued as rs770830936, COSV60196520; called by muse, mutect2, varscan2
- TRIP6 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99566369; called by muse, mutect2
- TSHB | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 125/486 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); catalogued as rs868014070, COSV56655954; called by muse, mutect2, varscan2
- TTN | c.25231G>A p.G8411S (on ENST00000591111; = p.G7484S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/510 reads (32%) | PolyPhen benign (0.018); catalogued as COSV60288502; called by muse, mutect2, varscan2
- UBE2D3 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.075); catalogued as rs563106506, COSV100414849, COSV57662550; called by muse, mutect2, varscan2
- UBE2O | c.2899A>G p.T967A | Missense Mutation (SNP) | VAF 51/54 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60066970; called by muse, mutect2, varscan2
- UROS | c.19A>C p.K7Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV64223987; called by muse, mutect2, varscan2
- USP8 | c.1052C>A p.T351K | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV100208575, COSV56166600; called by muse, mutect2
- WNK1 | c.6134A>C p.N2045T (on ENST00000315939 / NM_018979.4; = p.N1797T on NM_014823.3) | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60043169; called by muse, mutect2, varscan2
- WWC1 | c.557A>C p.Q186P | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV54657346; called by muse, mutect2, varscan2
- ZBTB25 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.977); catalogued as COSV67198901; called by muse, mutect2, varscan2
- ZNF236 | c.2517G>C p.L839F | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV53495906; called by muse, mutect2, varscan2
- ZNF451 | c.2186T>C p.I729T | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV62599633; called by muse, mutect2, varscan2
- ZNF750 | c.1988G>A p.C663Y | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.26); PolyPhen benign (0.079); catalogued as COSV53962411; called by muse, mutect2, varscan2
- ABHD17B | c.219_231del p.S74Efs*30 | Frame Shift Del (DEL) | VAF 36/388 reads (9%) | called by mutect2, pindel
- AEBP2 | c.760_795del p.S254_W265del | In Frame Del (DEL) | VAF 24/104 reads (23%) | called by mutect2, pindel
- CNTN6 | c.1237del p.S413Vfs*68 | Frame Shift Del (DEL) | VAF 36/190 reads (19%) | called by mutect2, pindel, varscan2
- DSC1 | c.1658_1663+1del p.X553_splice | Splice Site (DEL) | VAF 15/106 reads (14%) | called by mutect2, pindel, varscan2
- LAMA2 | c.6429+1_6429+9del p.X2143_splice | Splice Site (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- POT1 | c.1703_1715del p.I568Kfs*3 | Frame Shift Del (DEL) | VAF 59/117 reads (50%) | called by mutect2, pindel, varscan2
- WNK1 | c.5116_5162del p.T1706Cfs*37 (on ENST00000315939 / NM_018979.4; = p.T1459Cfs*37 on NM_014823.3) | Frame Shift Del (DEL) | VAF 30/262 reads (11%) | called by mutect2, pindel
- ABCA4 | c.4536C>A p.P1512= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs764982444, COSV64677002; called by muse, mutect2, varscan2
- AGBL1 | c.1998C>G p.P666= | Silent (SNP) | VAF 36/248 reads (15%) | catalogued as COSV101221816; called by mutect2, varscan2
- BTK | c.402C>T p.Y134= | Silent (SNP) | VAF 73/180 reads (41%) | catalogued as CD002495, CM960199, COSV58123188; called by muse, mutect2, varscan2
- CEP164 | c.3834C>A p.V1278= | Silent (SNP) | VAF 166/283 reads (59%) | catalogued as COSV54045550; called by muse, mutect2, varscan2
- CERKL | c.906C>A p.T302= (on ENST00000339098 / NM_001030311.2; = p.T276= on NM_201548.5) | Silent (SNP) | VAF 104/349 reads (30%) | catalogued as COSV100182840; called by muse, mutect2
- CHST4 | c.1083C>T p.H361= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs3813744, COSV100632765; called by muse, mutect2, varscan2
- DPYD | c.1180C>A p.R394= | Silent (SNP) | VAF 33/186 reads (18%) | catalogued as rs140602333, COSV64611853; called by muse, mutect2, varscan2
- GNL3L | c.1689T>C p.S563= | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as COSV60577431; called by muse, mutect2, varscan2
- IQGAP3 | c.2433G>A p.L811= | Silent (SNP) | VAF 190/586 reads (32%) | catalogued as rs200820791, COSV63254035; called by muse, mutect2, varscan2
- KCNH7 | c.2235C>G p.A745= | Silent (SNP) | VAF 68/436 reads (16%) | catalogued as COSV59810344; called by muse, mutect2, varscan2
- MLLT10 | c.2850G>A p.L950= (on ENST00000307729 / NM_001195626.3; = p.L966= on NM_004641.3) | Silent (SNP) | VAF 52/214 reads (24%) | catalogued as COSV57002973; called by muse, mutect2, varscan2
- MTNR1B | c.312C>T p.D104= | Silent (SNP) | VAF 207/352 reads (59%) | catalogued as rs139515067; called by muse, mutect2, varscan2
- MTREX | c.2172A>G p.G724= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV57929493; called by muse, mutect2, varscan2
- NAXD | c.579C>T p.A193= | Silent (SNP) | VAF 15/17 reads (88%) | catalogued as rs1224044402, COSV59395815; called by muse, mutect2, varscan2
- PPP1R18 | c.477C>A p.A159= | Silent (SNP) | VAF 96/243 reads (40%) | catalogued as COSV51298153; called by muse, mutect2, varscan2
- RBM26 | c.198G>A p.Q66= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV57399125; called by muse, mutect2, varscan2
- RIT2 | c.90A>C p.G30= | Silent (SNP) | VAF 74/238 reads (31%) | catalogued as COSV56307478, COSV56310330; called by muse, mutect2, varscan2
- SHCBP1 | c.576C>A p.A192= | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as COSV100317007; called by muse, mutect2
- SLC20A2 | c.1680G>A p.G560= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV60606398; called by muse, mutect2, varscan2
- SLC6A15 | c.114A>G p.E38= | Silent (SNP) | VAF 10/306 reads (3%) | catalogued as COSV99879850; called by muse, mutect2
- SPDYC | c.864G>T p.P288= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV65865601; called by muse, mutect2, varscan2
- STYXL2 | c.684C>T p.G228= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV54809179; called by muse, mutect2, varscan2
- TRIM33 | c.552C>T p.C184= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV100634949; called by muse, mutect2
- XRCC1 | c.1542G>C p.P514= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV53452463; called by muse, mutect2, varscan2
- ZNF117 | c.1371T>G p.S457= | Silent (SNP) | VAF 51/485 reads (11%) | catalogued as COSV51429518; called by muse, mutect2, varscan2
- LARS2 | c.*598C>G | 3'UTR (SNP) | VAF 16/72 reads (22%) | catalogued as COSV55531434; called by muse, mutect2, varscan2
- SGK1 | chr6:134177711 A>G | 5'Flank (SNP) | VAF 31/55 reads (56%) | catalogued as COSV99397526; called by muse, mutect2, varscan2
